Somatic mutation profile of tumor specimen 0DP8OB from CCDI case PBCDET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.1 years (1,865 days).
Specimen 0DP8OB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a37a104-8ca4-4fdb-a065-91730a966f3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP8O0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/223f1516-200a-48d6-924c-ea0b11a96d46

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 160/540 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- MAP3K21 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 184/758 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766605671, COSV64042349; called by muse, varscan2
- TG | c.2930C>G p.P977R | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.635); catalogued as COSV99601759; called by muse, varscan2
- TP53 | c.1020dup p.F341Vfs*6 | Frame Shift Ins (INS) | VAF 44/321 reads (14%) | catalogued as COSV99387854; called by pindel, varscan2
- LAMB4 | c.4673C>A p.A1558E | Missense Mutation (SNP) | VAF 136/358 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- FAM86C1P | n.434+84G>A | Intron (SNP) | VAF 20/132 reads (15%) | catalogued as rs540741288; called by muse, varscan2
- HAUS1 | c.-7C>T | 5'UTR (SNP) | VAF 24/167 reads (14%) | catalogued as rs1488717817; called by muse, varscan2
